Gene-level copy-number profile of tumor specimen TCGA-DX-A23T-01A from TCGA case TCGA-DX-A23T, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 40.8 years (14,892 days).
Specimen TCGA-DX-A23T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.08d96eb0-8653-4776-966e-d14e1956d4a7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A23T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/125578ac-0676-4c0a-9fd1-e82530cf0fc7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 55,707; copy number 3: 2,590; copy number 4: 879; copy number 5: 285; copy number 6: 142; copy number 7: 103; copy number 8: 39; copy number 9: 48; copy number 10: 9; copy number 11: 8; copy number 14: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A23T-01A-11D-A26F-01): tumor purity 0.28, ploidy 2.26, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 636 genes in 59 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:181,536,672–181,930,738, 8 genes, copy number 5 (within-gene range 2–5): CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2.
- chr5:116,085,016–117,722,097, 17 genes, copy number 5–8: COMMD10, RNU6-644P, HMGN2P27, AC018752.1, SEMA6A, SEMA6A-AS1, RPS14P8, SEMA6A-AS2, RPS17P2, LINC02214, AC010267.1, AC093534.1, AC093534.2, RPL35AP15, AC093295.1, LINC00992, AC114322.1.
- chr5:160,401,641–160,487,426, 5 genes, copy number 6 (within-gene range 3–6): SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A.
- chr5:162,000,057–165,783,134, 27 genes, copy number 5–8: GABRG2, AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938, AC008415.1, RN7SKP60, AC008562.1.
- chr5:180,826,871–181,342,213, 41 genes, copy number 5 (within-gene range 2–5): HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B, AC008620.2, OR2V1, OR2V2, LINC01962, AC008443.4, TRIM7, TRIM7-AS1, AC008443.3, AC008443.7, TRIM41, MIR4638, AC008443.1, RACK1, SNORD96A, SNORD95, CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.6, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr6:24,804,282–25,042,170, 4 genes, copy number 5–6 (within-gene range 2–6): RIPOR2, MTCO2P33, PPIAP29, ASS1P1.
- chr6:40,334,775–40,387,590, 3 genes, copy number 7: TDRG1, LINC00951, AL139275.1.
- chr6:131,901,963–133,990,432, 51 genes, copy number 6 (within-gene range 2–6): AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36, MOXD1, STX7, RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6, TAAR5, TAAR4P, AL513524.1, TAAR3P, TAAR2, TAAR1, HLFP1, VNN1, CCNG1P1, VNN3, VNN2, AL032821.1, RBM11P1, SLC18B1, RPS12, SNORD101, SNORD100, SNORA33, HMGB1P13, AL137783.1, LINC00326, RPL23AP46, AL591115.1, MTCYBP4, EYA4, AL024497.1, AL024497.2, TARID, HSPE1P21, AL450270.1, FTH1P26, LINC01312, TCF21, TBPL1, AL035699.1.
- chr6:142,058,330–144,136,775, 41 genes, copy number 5–8: NMBR, AL589674.1, NMBR-AS1, GJE1, VTA1, AL360007.1, ADGRG6, AL359313.1, AL355337.1, AL023584.1, HIVEP2, AL023584.2, AL355304.1, LINC01277, AL023581.2, AIG1, AL023581.1, AL136116.2, AL136116.1, AL136116.3, AL031320.1, ADAT2, TUBB8P2, RNA5SP221, PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3.
- chr6:145,296,545–145,964,423, 12 genes, copy number 6: AL023283.1, EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH.
- chr6:146,598,967–146,815,462, 3 genes, copy number 5 (within-gene range 2–5): ADGB, AL359547.2, RNU6-906P.
- chr6:148,567,378–149,411,613, 12 genes, copy number 6 (within-gene range 2–6): SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1.
- chr7:70,972–727,650, 21 genes, copy number 5 (within-gene range 3–5): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1.
- chr7:4,130,181–4,642,570, 3 genes, copy number 8: AC017000.1, CYP3A54P, AC072054.1.
- chr7:5,180,061–6,880,626, 60 genes, copy number 5: RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP, ZDHHC4, AC079742.1, C7orf26, ZNF853, ZNF316, AC073343.2, AC073343.1, ZNF12, PMS2CL, SPDYE20P, RSPH10B2, CCZ1B, OR7E39P, UNC93B2, OR7E136P, OR7E59P.
- chr8:2,045,046–2,165,552, 3 genes, copy number 5 (within-gene range 2–5): MYOM2, MIR7160, AC245164.2.
- chr8:14,022,687–15,238,431, 10 genes, copy number 6–7 (within-gene range 2–7): AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1.
- chr8:17,027,238–17,570,573, 13 genes, copy number 6 (within-gene range 2–6): MICU3, AC079193.2, AC079193.1, ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3.
- chr8:18,774,547–19,001,950, 6 genes, copy number 5: RPL35P6, AC087821.2, AC087821.1, SNORA62, AC009884.1, AC009884.2.
- chr8:22,219,703–22,357,568, 5 genes, copy number 5 (within-gene range 2–5): PHYHIP, MIR320A, POLR3D, AC105206.2, PIWIL2.
- chr8:22,544,986–22,575,788, 3 genes, copy number 8: SORBS3, AC037459.4, AC037459.3.
- chr8:29,527,312–29,632,644, 4 genes, copy number 6–9: AC084026.2, AC084026.1, AC084026.3, RPL17P33.
- chr8:48,515,852–50,796,692, 25 genes, copy number 7 (within-gene range 2–7): AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2.
- chr8:66,493,520–66,962,591, 12 genes, copy number 5 (within-gene range 2–5): VXN, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24.
- chr8:67,952,046–68,237,032, 4 genes, copy number 5 (within-gene range 3–5): PREX2, AC011853.2, AC011853.1, Y_RNA.
- chr8:71,675,300–72,950,445, 18 genes, copy number 5: AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2.
- chr8:75,120,409–75,352,327, 3 genes, copy number 6: CASC9, LINC02886, HIGD1AP6.
- chr11:96,352,769–96,507,574, 2 genes, copy number 6 (within-gene range 2–6): CCDC82, JRKL.
- chr11:101,208,905–101,872,562, 4 genes, copy number 7 (within-gene range 2–7): AP001533.1, TRPC6, MIR3920, AP003080.1.
- chr11:101,890,674–103,092,194, 39 genes, copy number 5–9 (within-gene range 2–9): ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2.
- chr11:104,942,866–107,457,844, 35 genes, copy number 5–11 (within-gene range 2–11): CASP4, AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP, GRIA4, HSPD1P13, RNU4-55P, RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1.
- chr12:55,009,746–55,030,017, 2 genes, copy number 8: AC027287.2, NEUROD4.
- chr12:56,981,211–57,213,361, 12 genes, copy number 6: AC026120.1, AC026120.3, GPR182, ZBTB39, TAC3, MYO1A, NEMP1, NAB2, STAT6, LRP1, LRP1-AS, MIR1228.
- chr12:57,619,527–57,984,761, 30 genes, copy number 7: SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:63,558,913–64,222,296, 18 genes, copy number 5 (within-gene range 3–5): DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66.
- chr12:65,934,777–66,170,072, 9 genes, copy number 6–7: AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:68,143,318–68,553,882, 11 genes, copy number 6–10: AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12.
- chr12:68,686,951–69,699,476, 30 genes, copy number 9 (within-gene range 2–9): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr13:103,343,660–103,444,968, 3 genes, copy number 8: AL162717.1, LINC01309, ATP6V1G1P7.
- chr21:19,130,523–19,345,312, 4 genes, copy number 8: AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
